Surgical pathology report (de-identified scan), TCGA case TCGA-19-1385, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-1385-01A (Primary Tumor).

[page 1 of 3]
19-1385

DATE/TIME:

RESULTS DETAIL

PATIENT NAME: ~~XXXXXXXXXX~~

BIRTHDATE: ~~XXXXXXXXXX~~

SEX: ~~XXXXXX~~

PATIENT #: ~~XXXXXXXXXX~~ VISIT: ~~XXXXXXXXXX~~

PAGE 001 OF 008 FOR TEST 001 OF 001

Accession #: ~~XXXXXXXXXX~~ Date of Procedure: ~~XXXXXXXXXX~~

Pathologist: ~~XXXXXXXXXX~~

Date Reported: ~~XXXXXXXXXX~~

Date Received: ~~XXXXXXXXXX~~

Submitting Physician: ~~XXXXXXXXXX~~

Attending Physician: ~~XXXXXXXXXX~~

FINAL DIAGNOSIS

A. RIGHT POSTERIOR OCCIPITAL TUMOR, RESECTION:

--GLIOBLASTOMA MULTIFORME, WHO GRADE IV.

B. SPECIMEN LABELED AS "PERMANENT", RESECTION:

--GLIOBLASTOMA MULTIFORME, WHO GRADE IV. SEE NOTE.

ENTER=CONTINUE

F1=HELP

F2=

F3=

F4=

F5=PAT SEL

F6=EXAM SUM.

F7=

F8=NEXT PAGE

F11=MORE FKEYS

[page 2 of 3]
Note: Tumor cells are positive for GFAP immunostain. KI-67 immunostain is positive in many tumor cells.

C. SPECIMEN IS LABELED AS "CENTER", RESECTION:
--GLIOBLASTOMA MULTIFORME, WHO GRADE IV WITH EXTENSIVE NECROSIS.

D. SPECIMEN IS LABELED AS "EDGE", RESECTION:
--GLIOBLASTOMA MULTIFORME, WHO GRADE IV WITH EXTENSIVE NECROSIS.

E. SPECIMEN IS LABELED AS "WHITE MATTER", RESECTION:
--FRAGMENTS OF WHITE MATTER WITH SLIGHT HYPERCELLULARITY. SEE NOTE.

Note: The sections show slightly hypercellular white matter with rare atypical

ENTER=CONTINUE	F1=HELP	F2=	F3=	F4=
F5=PAT SEL	F6=EXAM SUM.	F7=PREV PAGE	F8=NEXT PAGE	F11=MORE FKEYS

[page 3 of 3]
[REDACTED]

cells.

Note

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASR's). ASR's have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by the Department of Pathology at [REDACTED] The assays were performed with appropriate positive and negative controls.

Electronically Signed Out By [REDACTED]

ENTER=CONTINUE	F1=HELP	F2=	F3=	F4=
F5=PAT SEL	F6=EXAM SUM.	F7=PREV PAGE	F8=NEXT PAGE	F11=MORE FKEYS

Source: NCI Genomic Data Commons file cbe67258-3448-498f-9cc7-0ffc18dc57bf (TCGA-19-1385.BA34C5C0-BA80-4200-942C-F709D7ACF69C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).